Somatic mutation profile of tumor specimen C3L-06537-54 (aliquot CPT0357600002) from CPTAC case C3L-06537, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 39.9 years (14,567 days).
Specimen C3L-06537-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01c6d5f5-96ba-4dd1-aac1-f6e43727195f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06537-51 (Buccal Cell Normal), aliquot CPT0357570003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7370af60-59f9-4106-99bb-422d54202b51

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2447A>T p.D816V | Missense Mutation (SNP) | VAF 40/232 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs121913507, CM952169, COSV55386424, COSV55388612, COSV55408930; ClinVar: other / uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- LPA | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 71/377 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.243); catalogued as rs775410119, COSV60296372; called by muse, mutect2, varscan2
- ATP8B1 | c.3046C>T p.P1016S | Missense Mutation (SNP) | VAF 11/260 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- CCDC22 | c.637C>A p.Q213K | Missense Mutation (SNP) | VAF 28/204 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- FAT1 | c.10429T>G p.F3477V | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- LINC01804 | n.445C>T | RNA (SNP) | VAF 34/88 reads (39%) | catalogued as rs1053268540; called by muse, mutect2, varscan2
